MMRF case MMRF_2167 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2f5e648f-7cc3-44db-8c84-a7b8ffcccf97

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Dead; Days to death: 839 days (2.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.3 years (25,665 days); ISS stage: III; Days to last known disease status: 839 days (2.3 years); Days to last follow up: 839 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 185 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 4 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 10 days; Days to treatment end: 194 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 201 days; Days to treatment end: 299 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 201 days; Days to treatment end: 307 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 333 days; Days to treatment end: 333 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 336 days; Days to treatment end: 336 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 454 days (1.2 years); Days to treatment end: 531 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 460 days (1.3 years); Days to treatment end: 839 days (2.3 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 460 days (1.3 years); Days to treatment end: 517 days (1.4 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 517 days (1.4 years); Days to treatment end: 833 days (2.3 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 524 days (1.4 years); Days to treatment end: 622 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 636 days (1.7 years); Days to treatment end: 824 days (2.3 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 678 days (1.9 years); Days to treatment end: 823 days (2.3 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 825 days (2.3 years); Days to treatment end: 825 days (2.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 839.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 2): M Protein 1.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.1 mg/dL; Immunoglobulin G 19.5 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 10.5 µg/mL; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 11 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 271 µmol/L; Blood Urea Nitrogen 15.4 mmol/L; Calcium 4.25 mmol/L; Albumin 38 g/L; Total Protein 8.1 g/dL; Glucose 7.7 mmol/L; C-Reactive Protein 0.5 mg/dL.
- Day 87 (ECOG 1): M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.951 mg/dL; Immunoglobulin G 7.12 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 330 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.94 mmol/L.
- Day 194 (ECOG 1): M Protein 0.81 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 175 mg/dL; Immunoglobulin G 9.08 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 6.52 µg/mL; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 187 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.58 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 6.27 mmol/L.
- Day 283 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.91 mg/dL; Immunoglobulin G 5.04 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 362 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 4.84 mmol/L.
- Day 374 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.586 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.979 mg/dL; Immunoglobulin G 4.42 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 7.49 ×10⁹/L; Absolute Neutrophil 5.74 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 5.89 mmol/L.
- Day 451 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.08 mg/dL; Immunoglobulin G 5.56 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.63 ×10⁹/L; Absolute Neutrophil 3.69 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 5.94 mmol/L.
- Day 552 (ECOG 1): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.394 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.9 mg/dL; Immunoglobulin G 4.45 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.18 ×10⁹/L; Absolute Neutrophil 1.29 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 35 g/L; Total Protein 5.6 g/dL; Glucose 5.83 mmol/L.
- Day 636 (ECOG 1): M Protein 0.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 67.9 mg/dL; Immunoglobulin G 4.78 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 5.79 ×10⁹/L; Absolute Neutrophil 3.05 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 173 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.48 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 6.6 mmol/L.
- Day 734 (ECOG 3): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.48 mg/dL; Immunoglobulin G 3 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 3.79 ×10⁹/L; Absolute Neutrophil 2.45 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 5.6 g/dL; Glucose 6.77 mmol/L.
- Day 816 (ECOG 3): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 167 mg/dL; Immunoglobulin G 3 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 9.44 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 9.13 ×10⁹/L; Absolute Neutrophil 7.48 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 5.1 g/dL; Glucose 11.4 mmol/L.

Other clinical attributes
- Day 0: Weight: 113 kg; Height: 178 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2167_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2167_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
